Somatic mutation profile of tumor specimen TCGA-AB-2809-03D (aliquot TCGA-AB-2809-03D-01W-0755-09) from TCGA case TCGA-AB-2809, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute promyelocytic leukaemia, t(15;17)(q22;q11-12); Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.8 years (23,679 days).
Specimen TCGA-AB-2809-03D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e665e5c1-d17f-4fb7-9392-b9fe07525475.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2809-11D (Solid Tissue Normal), aliquot TCGA-AB-2809-11D-01W-0755-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46371551-8b44-4788-8660-c669228dea37

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAGI2 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV100834859; called by muse, mutect2, varscan2
